Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7294, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7294-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Ambulatory Surgery

[REDACTED]

[REDACTED]

UPDATED REPORT [REDACTED] - SEE SPECIAL STAIN REPORT
UPDATED REPORT [REDACTED] SEE ADDENDUM REPORT

PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, FRONTAL, EXCISION: OLIGODENDROGLIOMA.

SEE COMMENT.

Operation/Specimen: UPDATED REPORT - Brain tumor.

Clinical History and Pre-Op Dx: [REDACTED] woman with non-enhancing frontal brain tumor.

GROSS PATHOLOGY:

A. Received fresh, one fragment, 0.5 cm across. Semi-firm, yellowish-white. In total #1.

INTRAOPERATIVE CONSULTATION: Brain, smears: Glioma (oligodendroglial).

B.

SPECIMEN: Brain tumor.

FIXATIVE: None.

GENERAL: Received fresh for permanents, is a 3 x 3 x 1 cm. aggregate of soft pink-tan brain tissue.

SECTIONS: Specimen is submitted in total in blocks 2B-3B.

[REDACTED]

COMMENT: The specimens contain cerebral cortex and white matter that are diffusely infiltrated by a glial neoplastic proliferation. The neoplastic cells have uniform round nuclei devoid of cytoplasm, and display prominent perineuronal satellitosis. Focally, the neoplastic cells have perinuclear halos. There is slight pleomorphism, and mitotic figures, microvascular cellular proliferation, and necrosis are

[page 2 of 2]
absent. The phenotype of the tumor is that of one with loss of heterozygosity.

ADDENDUM REPORT

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, CD34, p53, and MIB-1 were performed on sections from block #3.

The GFAP demonstrates scant gliofibrillogenesis. The CD34 depicts a capillary-type microvasculature, without microvascular cellular proliferation. The neoplastic cells do not overexpress the p53 protein. With the MIB-1 a proliferation index of about 2% is determined in the more active areas.

SPECIAL STAIN REPORT: Bielschowsky stain was performed on sections from block #3.

The special stain demonstrates no distortion of the normal axonal pattern by the neoplastic cells.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file d90b5926-957f-4dd2-ace3-a4937c8f04ba (TCGA-DU-7294.3F73EAA4-67DA-4C34-98A1-8D4DB2997272.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).